Somatic mutation profile of tumor specimen TCGA-AX-A05T-01A (aliquot TCGA-AX-A05T-01A-11W-A027-09) from TCGA case TCGA-AX-A05T, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 82.5 years (30,137 days).
Specimen TCGA-AX-A05T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c41fbc34-392a-4273-b4ab-44c63864a7f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A05T-10A (Blood Derived Normal), aliquot TCGA-AX-A05T-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04836396-2ea0-4f94-a607-afb777b4396d

The open-access MAF lists 54 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 31, Silent 13, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 46/103 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 95/237 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.97_99del p.I33del | In Frame Del (DEL) | VAF 263/304 reads (87%) | catalogued as rs1554893765; ClinVar: uncertain significance / likely pathogenic; called by pindel, varscan2
- CAB39L | c.994T>G p.L332V | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV61715449; called by muse, mutect2, varscan2
- CAMK4 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV99998800; called by muse, mutect2
- CHD4 | c.3413A>C p.H1138P (on ENST00000357008 / NM_001363606.2; = p.H1151P on NM_001273.5) | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV58903706, COSV58909861; called by muse, mutect2, varscan2
- CNTNAP4 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 27/606 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs774984327, COSV100270478, COSV56678542; called by muse, mutect2
- COL7A1 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779142959, COSV60396845; called by muse, mutect2, varscan2
- CSF3 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56641233; called by muse, mutect2, varscan2
- CTNND1 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475157781, COSV62382654; called by muse, mutect2, varscan2
- EPHA5 | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1229443873, COSV56651742; called by muse, mutect2, varscan2
- FAM216B | c.272C>A p.S91* | Nonsense Mutation (SNP) | VAF 84/183 reads (46%) | catalogued as COSV58269922, COSV58270659; called by muse, mutect2, varscan2
- FMNL2 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as COSV56497524; called by muse, mutect2, varscan2
- GSTA5 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 163/440 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as rs759910242, COSV52862924; called by muse, mutect2, varscan2
- H2BC15 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV57585861; called by muse, mutect2, varscan2
- KCNQ5 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV59669471; called by muse, mutect2
- KLHL4 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.042); catalogued as rs1349335740, COSV64143859; called by muse, mutect2, varscan2
- LRP1 | c.8371C>T p.R2791C | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs755214895, COSV54515141; called by muse, mutect2, varscan2
- LRRC55 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV73006640; called by muse, mutect2, varscan2
- NPAP1 | c.2603C>T p.S868L | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV61508161; called by muse, mutect2, varscan2
- OR8J3 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs756092293, COSV56881992; called by muse, mutect2, varscan2
- PTCH1 | c.2198C>A p.S733* | Nonsense Mutation (SNP) | VAF 87/178 reads (49%) | catalogued as CD972416, COSV100107444, COSV59479700; called by muse, mutect2, varscan2
- PZP | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV54363112; called by muse, mutect2, varscan2
- RGL2 | c.1371T>G p.F457L | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65842416; called by muse, mutect2, varscan2
- RINL | c.1522C>T p.H508Y (on ENST00000591812 / NM_001195833.2; = p.H394Y on NM_198445.4) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV61574956; called by muse, mutect2, varscan2
- RPAP2 | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 172/422 reads (41%) | catalogued as rs773715191, COSV72101558; called by muse, mutect2, varscan2
- SHROOM4 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV56791278; called by muse, mutect2, varscan2
- STIP1 | c.1624A>G p.I542V | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.471); catalogued as rs766923089, COSV54180928; called by muse, mutect2, varscan2
- TBC1D14 | c.1477A>G p.I493V | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV68986215; called by muse, mutect2, varscan2
- TMEM127 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs149034651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM14B | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65356147; called by muse, mutect2, varscan2
- UQCC1 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62902537, COSV62902768; called by muse, mutect2, varscan2
- VWA3B | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 108/290 reads (37%) | catalogued as rs556249595, COSV68243896; called by muse, mutect2, varscan2
- XPNPEP2 | c.106T>C p.C36R | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as COSV64367994; called by muse, mutect2
- XYLT1 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.616); catalogued as rs551025574, COSV54487498, COSV99077146; called by muse, mutect2, varscan2
- ZDHHC15 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.281); catalogued as COSV64902329; called by muse, mutect2, varscan2
- ARID1A | c.3040_3041dup p.G1015Wfs*25 | Frame Shift Ins (INS) | VAF 76/117 reads (65%) | called by mutect2, pindel, varscan2
- CTCF | c.770_774del p.I257Kfs*11 | Frame Shift Del (DEL) | VAF 51/128 reads (40%) | called by mutect2, pindel, varscan2
- PTMA | c.251_252del p.E84Vfs*9 (on ENST00000341369 / NM_001099285.2; = p.E83Vfs*9 on NM_002823.5) | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- RBM27 | c.2603_2604del p.E868Afs*11 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | called by pindel, varscan2
- TIMM23 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 163/372 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTTNBP2 | c.4311C>T p.S1437= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs1267887888, COSV50412068; called by muse, mutect2, varscan2
- DAGLB | c.21C>T p.F7= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1424326924, COSV51704798; called by muse, mutect2, varscan2
- DDX53 | c.321G>A p.A107= | Silent (SNP) | VAF 85/212 reads (40%) | catalogued as COSV60069376; called by muse, mutect2, varscan2
- DHRS13 | c.915G>A p.E305= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV66684078; called by muse, mutect2, varscan2
- DYNAP | c.585C>T p.A195= (on ENST00000321600; = p.A169= on NM_173629.3) | Silent (SNP) | VAF 115/303 reads (38%) | catalogued as rs200666940, COSV58666522; called by muse, mutect2, varscan2
- MED13L | c.6510G>A p.L2170= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as COSV56122681; called by muse, mutect2, varscan2
- MOAP1 | c.468C>G p.A156= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV52092855; called by muse, mutect2, varscan2
- OGFRL1 | c.978G>A p.Q326= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as COSV64972110; called by muse, mutect2
- PCDH17 | c.1704G>A p.T568= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV64975409, COSV64977188; called by muse, mutect2, varscan2
- PCDHA7 | c.297C>T p.S99= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as rs1554134423, COSV65344985; called by muse, mutect2, varscan2
- SEZ6L | c.2478G>T p.V826= | Silent (SNP) | VAF 50/104 reads (48%) | catalogued as COSV50668291, COSV50668348; called by muse, mutect2, varscan2
- SLC25A19 | c.906G>A p.S302= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs145808509; ClinVar: likely benign; called by muse, mutect2, varscan2
- TEKT1 | c.570G>A p.S190= | Silent (SNP) | VAF 82/204 reads (40%) | catalogued as rs762864188, COSV58623562; called by muse, mutect2, varscan2
